Somatic mutation profile of tumor specimen TCGA-AZ-4323-01A (aliquot TCGA-AZ-4323-01A-21D-1835-10) from TCGA case TCGA-AZ-4323, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 37.7 years (13,755 days).
Specimen TCGA-AZ-4323-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee621650-e848-4f35-8707-5b0810a1acc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-4323-10A (Blood Derived Normal), aliquot TCGA-AZ-4323-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/089c7c32-abc0-42ab-b453-de90340e8b6e

The open-access MAF lists 45 somatic variants for this specimen: 33 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 28, Silent 12, Nonsense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.4243C>T p.R1415* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as rs754129466, COSV60103724; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCOR | c.3649C>T p.R1217* (on ENST00000378444 / NM_001123385.2; = p.R1183* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as CM1313413, COSV60700105, COSV60714720; called by muse, mutect2, varscan2
- BCORL1 | c.3391C>T p.Q1131* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV54409739; called by muse, mutect2, varscan2
- CNTN3 | c.1858G>T p.E620* | Nonsense Mutation (SNP) | VAF 13/268 reads (5%) | catalogued as COSV55161799; called by muse, mutect2
- COL11A1 | c.812A>C p.Y271S | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.969); catalogued as COSV62202030; called by muse, mutect2, varscan2
- COL4A6 | c.3593G>T p.G1198V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100563203; called by muse, mutect2, varscan2
- COL9A1 | c.1653G>A p.M551I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.146); catalogued as COSV100293919; called by muse, varscan2
- CXorf58 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs764120865, COSV64858058; called by muse, mutect2, varscan2
- DIAPH2 | c.1218T>G p.N406K | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV100230404; called by muse, mutect2
- E4F1 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1316610361, COSV57041829; called by muse, mutect2, varscan2
- FCGR3A | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs370288605; called by muse, mutect2
- FREM1 | c.3717T>G p.H1239Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771795372, COSV101083674; called by muse, varscan2
- KIF2B | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs868793706, COSV52127761; called by muse, mutect2, varscan2
- LARS1 | c.246A>T p.K82N | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV50996336; called by muse, mutect2
- MAGI1 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776804460, COSV58349681; called by muse, mutect2, varscan2
- MCM3 | c.1576G>A p.D526N (on ENST00000229854 / NM_001366374.2; = p.D516N on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.75); catalogued as rs1267517157, COSV57719079; called by muse, mutect2, varscan2
- MDM1 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 12/204 reads (6%) | catalogued as COSV100291567; called by muse, mutect2
- MUC16 | c.43198C>T p.R14400W | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.981); catalogued as rs934266980, COSV66690679; called by muse, varscan2
- MYOZ3 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV51741463; called by muse, mutect2
- OR4K2 | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as COSV100063995, COSV100064530; called by muse, mutect2
- OSBPL9 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs776013856, COSV61870264; called by muse, mutect2, varscan2
- PASD1 | c.1768C>A p.P590T | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.352); catalogued as COSV64858441; called by muse, mutect2
- PRUNE1 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV99639120; called by muse, mutect2, varscan2
- RAPGEF1 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV100940237; called by muse, mutect2, varscan2
- SLCO6A1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1474060384, COSV65806425; called by muse, mutect2, varscan2
- SRCAP | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs970002773, COSV52677778; called by muse, mutect2, varscan2
- SYNE1 | c.16670A>C p.N5557T (on ENST00000367255 / NM_182961.4; = p.N5486T on NM_033071.3) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99551505; called by muse, mutect2
- TAAR6 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV51583101; called by muse, mutect2, varscan2
- TMEM63A | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.816); catalogued as rs778512108, COSV64764518; called by mutect2, varscan2
- TP53 | c.485T>A p.I162N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM983887, COSV52662176, COSV52713754, COSV53430175; called by muse, mutect2
- ZNF280C | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1444015463, COSV63968830; called by muse, mutect2
- ZNF839 | c.1150C>A p.L384I (on ENST00000558850 / NM_001267827.1; = p.L500I on NM_018335.5) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99216028; called by muse, mutect2, varscan2
- SLC10A2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- ADGRG4 | c.5220T>G p.T1740= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV54957839, COSV99797221; called by muse, mutect2
- CFAP54 | c.6114A>G p.K2038= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100732901; called by muse, mutect2, varscan2
- CTNND2 | c.507G>A p.P169= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs146087152; called by muse, mutect2, varscan2
- FLG | c.5895C>T p.A1965= | Silent (SNP) | VAF 34/492 reads (7%) | catalogued as rs147091039; called by muse, mutect2
- KCNH2 | c.3471G>A p.P1157= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs562609392, COSV51129679; called by muse, mutect2, varscan2
- KIF2B | c.1449G>A p.L483= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- LINGO2 | c.1725C>T p.N575= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs768585401, COSV58065593; called by muse, mutect2, varscan2
- MYO18A | c.2472C>T p.H824= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs367888758; called by mutect2, varscan2
- P4HA1 | c.591C>T p.G197= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs201200914, COSV54960120, COSV54964078; called by mutect2, varscan2
- SCN2A | c.2247A>G p.K749= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV51858595; called by muse, mutect2, varscan2
- TBXT | c.267C>A p.S89= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV51620625; called by muse, mutect2, varscan2
- XRCC5 | c.1084C>T p.L362= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV67538385; called by muse, mutect2
